Somatic mutation profile of tumor specimen 0DB12I from CCDI case PBBKPY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 9.8 years (3,573 days).
Specimen 0DB12I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca353177-37c5-400a-ba95-ce93136c0381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB12P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0feacdf7-f17f-436f-a71e-310a68290875

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 3, Silent 2, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1S | c.1441A>G p.R481G | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs782817093; called by muse, mutect2, varscan2
- IL31RA | c.1789del p.I597* | Frame Shift Del (DEL) | VAF 42/366 reads (11%) | called by mutect2, varscan2
- MYO5A | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- ZNF776 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NOVA1 | c.1083A>G p.L361= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs1471429876, COSV57479194; called by muse, mutect2
- REPS2 | c.33A>G p.A11= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1333262642; called by muse, varscan2
- CAPN7 | c.2074-48del | Intron (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- DOCK10 | c.3702+57A>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs922590565; called by mutect2, varscan2
- MAFG | c.*50C>T | 3'UTR (SNP) | VAF 3/13 reads (23%) | catalogued as rs1485242279; called by muse, varscan2
- PAQR9 | c.-28C>T | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- PUF60 | c.348+10A>C | Intron (SNP) | VAF 10/253 reads (4%) | called by muse, mutect2
